Somatic mutation profile of tumor specimen TCGA-EM-A2CR-01A (aliquot TCGA-EM-A2CR-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CR, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 46.0 years (16,807 days).
Specimen TCGA-EM-A2CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8950837c-1828-4542-a6ac-8e7cb1b46cd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CR-10A (Blood Derived Normal), aliquot TCGA-EM-A2CR-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c28f153-7203-4819-b141-287fe84a0659

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 68/183 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CXCL13 | c.279A>T p.K93N | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV54489286; called by muse, mutect2, varscan2
- DGCR8 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100707762, COSV61225642; called by muse, mutect2, varscan2
- NEK8 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs757554273, COSV52043237; called by muse, mutect2, varscan2
- PRB2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 137/452 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as rs779871868, COSV66982352; called by muse, varscan2
- RRN3 | c.1330A>G p.T444A | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99548753; called by muse, mutect2, varscan2
- RAB37 | c.172del p.I58Sfs*8 | Frame Shift Del (DEL) | VAF 47/146 reads (32%) | called by mutect2, pindel, varscan2
- SIRPB1 | c.996G>A p.V332= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as rs1214560760, COSV53537713; called by muse, mutect2, varscan2
- AK9 | c.3633+13_3633+15del | Intron (DEL) | VAF 4/37 reads (11%) | catalogued as rs201441562; called by pindel, varscan2
